Somatic mutation profile of tumor specimen C3N-02296-02 (aliquot CPT0181750007) from CPTAC case C3N-02296, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 83.3 years (30,417 days).
Specimen C3N-02296-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ac3e557-028e-4ade-842a-6f57614d0cd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02296-31 (Blood Derived Normal), aliquot CPT0181800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e1746e4-e509-4ea9-a234-720285071ac6

The open-access MAF lists 665 somatic variants for this specimen: 435 protein-altering or splice-affecting, 151 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 151, Frame Shift Del 71, Intron 46, Nonsense Mutation 23, Frame Shift Ins 18, 3'UTR 12, RNA 9, 5'UTR 6, Splice Region 6, Splice Site 5, In Frame Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4338dup p.P1447Tfs*22 | Frame Shift Ins (INS) | VAF 58/189 reads (31%) | catalogued as rs781126037; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.7327C>T p.R2443* | Nonsense Mutation (SNP) | VAF 20/350 reads (6%) | catalogued as rs121434220, CM960104, COSV53724743, COSV53745412; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PCDH15 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 49/358 reads (14%) | catalogued as rs370261904, CM142132, COSV57375167; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 534/593 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.6671G>A p.R2224H | Missense Mutation (SNP) | VAF 218/542 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs537994744, COSV62094468; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs531684936, COSV56846952, COSV56857515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 148/420 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202103893, COSV53973931; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ABHD3 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV100004537; called by muse, varscan2
- ADAMTSL4 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs149442347; called by muse, varscan2
- ADARB2 | c.689del p.P230Rfs*54 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs1304178969, COSV101187413; called by mutect2, pindel, varscan2
- ADCK1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 162/416 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs773292041, COSV53086956; called by muse, mutect2, varscan2
- ADCY1 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs1286827331; called by muse, mutect2, varscan2
- AHRR | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1282181619, COSV57085921; called by muse, mutect2, varscan2
- ALOX15B | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs375708086, COSV66479103; called by muse, mutect2, varscan2
- AMOTL1 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368527730; called by muse, mutect2, varscan2
- AMPD3 | c.362C>T p.T121M (on ENST00000396553 / NM_001025389.2; = p.T130M on NM_000480.3) | Missense Mutation (SNP) | VAF 180/473 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780348844, COSV67330561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKS3 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 78/456 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356244572; called by muse, mutect2, varscan2
- APC | c.4366A>T p.K1456* | Nonsense Mutation (SNP) | VAF 74/176 reads (42%) | catalogued as COSV57338380; called by muse, mutect2, varscan2
- ARFGEF2 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 165/378 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64214556; called by muse, mutect2, varscan2
- ARHGAP39 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs759975258, COSV52767288; called by muse, mutect2, varscan2
- ARNTL2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749536664, COSV53827732; called by muse, mutect2, varscan2
- B4GALNT4 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755857098; called by muse, mutect2, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as rs749168305; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 76/202 reads (38%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD4 | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs1220564612; called by muse, mutect2, varscan2
- BRINP2 | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.338); catalogued as rs752069766; called by muse, mutect2, varscan2
- BRPF1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57406846; called by muse, mutect2, varscan2
- BRSK2 | c.1063dup p.R355Pfs*48 | Frame Shift Ins (INS) | VAF 126/346 reads (36%) | catalogued as rs779380593; called by mutect2, varscan2
- BTBD7 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs915971782; called by muse, mutect2, varscan2
- C1GALT1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs767692066; called by muse, mutect2, varscan2
- C1QTNF2 | c.391C>T p.R131W (on ENST00000393975; = p.R86W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs545651547; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 39/175 reads (22%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C3orf20 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs145497672; called by muse, mutect2, varscan2
- CACNG3 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 139/335 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50075080; called by muse, mutect2, varscan2
- CBARP | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99289524; called by muse, mutect2, varscan2
- CBLN1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54654766; called by muse, mutect2, varscan2
- CCDC87 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 154/328 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs369370998; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 29/177 reads (16%) | catalogued as rs760923345; called by mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 80/230 reads (35%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDT1 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 170/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766150941; called by muse, mutect2, varscan2
- CELSR2 | c.3905G>A p.R1302H | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs769079305; called by muse, mutect2, varscan2
- CEP164 | c.1481dup p.P495Sfs*43 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs752518735; called by mutect2, varscan2
- CLK4 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171473447, COSV60320552; called by muse, mutect2, varscan2
- CNPPD1 | c.1128del p.W377Gfs*36 | Frame Shift Del (DEL) | VAF 39/143 reads (27%) | catalogued as rs764842458; called by mutect2, varscan2
- CSMD3 | c.10052C>A p.S3351Y (on ENST00000297405 / NM_001363185.1; = p.S3182Y on NM_052900.3) | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV52137625, COSV99838503; called by muse, mutect2
- CSRNP3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770309060, COSV100085635; called by muse, mutect2, varscan2
- CUX2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199526069; called by muse, mutect2, varscan2
- CYP2D7 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 201/390 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs746181155, COSV100809736, COSV100809751; called by muse, mutect2, varscan2
- DAB2IP | c.1570C>T p.R524C (on ENST00000408936; = p.R496C on NM_032552.3) | Missense Mutation (SNP) | VAF 181/470 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408800095, COSV52258387; called by muse, mutect2, varscan2
- DMD | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs939660481; called by muse, mutect2, varscan2
- DNAH5 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763771549, COSV54216174; called by muse, mutect2, varscan2
- DNMT1 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 302/720 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV61577509; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs782552436; called by mutect2, varscan2
- DRG1 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV58920317; called by muse, mutect2, varscan2
- DUSP8 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs553329941; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- EDC3 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as rs148327581; called by muse, mutect2, varscan2
- EIF3B | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as rs1341769799; called by muse, mutect2, varscan2
- ELP5 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs147755585, COSV100598131; called by muse, mutect2
- ENPP7 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375944593, COSV100093501; called by muse, mutect2, varscan2
- EPB41L4A | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as rs778624919, COSV54866208; called by muse, mutect2, varscan2
- EPB41L4B | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779515974, COSV65796418; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs753821453; called by mutect2, varscan2
- FAM71A | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1425193974; called by muse, mutect2, varscan2
- FANCE | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 185/451 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs150278839; called by muse, mutect2, varscan2
- FBLIM1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 141/344 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1185829200; called by muse, mutect2, varscan2
- FBLN5 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 19/560 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50908202; called by muse, mutect2
- FBXO46 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as rs374779717; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1288807478; called by mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 24/188 reads (13%) | catalogued as rs756304971; called by mutect2, varscan2
- GIGYF1 | c.1664A>G p.Q555R | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs753191004; called by muse, mutect2, varscan2
- GIPC1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs761799155; called by muse, mutect2, varscan2
- GJB4 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.394); catalogued as rs185327282; called by muse, mutect2, varscan2
- GJB5 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 157/391 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199724435; called by muse, mutect2, varscan2
- GLI3 | c.3622G>A p.G1208R | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.166); catalogued as rs369440387, COSV67884694; called by muse, mutect2, varscan2
- GNA14 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 229/537 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1197170791, COSV59027967; called by muse, mutect2, varscan2
- GOLGA3 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99202240; called by muse, mutect2, varscan2
- GRAMD1A | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773224886; called by muse, mutect2, varscan2
- GSAP | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs375125347; called by muse, mutect2, varscan2
- GSE1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs199961563, COSV53670208; called by muse, mutect2, varscan2
- GUCY2C | c.3165dup p.G1056Rfs*25 | Frame Shift Ins (INS) | VAF 131/361 reads (36%) | catalogued as rs1565600862; called by mutect2, pindel, varscan2
- HDAC3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179991492; called by muse, mutect2, varscan2
- HECTD4 | c.9185C>T p.P3062L | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348349656, COSV66390854, COSV66392995; called by muse, mutect2, varscan2
- HIPK3 | c.2021C>T p.T674M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs367997325; called by muse, mutect2, varscan2
- HOOK3 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 59/143 reads (41%) | catalogued as rs1449147637; called by muse, mutect2, varscan2
- HOXC13 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043586760, COSV54499574; called by muse, mutect2, varscan2
- HPS5 | c.2561G>A p.R854Q (on ENST00000349215 / NM_181507.2; = p.R740Q on NM_007216.4) | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs200189057; called by muse, mutect2, varscan2
- HSPG2 | c.10001G>A p.R3334H | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746201509; called by muse, mutect2, varscan2
- IGSF21 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 141/338 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs759051309, COSV52125229; called by muse, mutect2, varscan2
- IL12RB2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746456201, COSV52022463, COSV52025285; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | catalogued as rs760925109; called by mutect2, pindel
- INTU | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs370165526; called by muse, mutect2, varscan2
- IQCN | c.3221G>T p.R1074L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs772258185; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs771739474; called by mutect2, varscan2
- IRS2 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 130/257 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1316344339; called by muse, mutect2, varscan2
- ITGAE | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200442248; called by muse, mutect2, varscan2
- KBTBD11 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs989870299; called by muse, mutect2, varscan2
- KCNB1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65565964, COSV65567065; called by muse, mutect2, varscan2
- KCNH5 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs148002630, COSV59766398; called by muse, mutect2
- KCNQ3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 101/388 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as rs201688404, COSV66476874; called by mutect2, varscan2
- KIF26A | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100181113; called by muse, mutect2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 53/132 reads (40%) | catalogued as rs771825279; called by mutect2, pindel, varscan2
- KLF2 | c.261del p.A88Rfs*53 | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | catalogued as rs1302376110; called by mutect2, pindel, varscan2
- KLK10 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs762681073, COSV59397818; called by muse, mutect2, varscan2
- LIM2 | c.319dup p.S107Ffs*59 (on ENST00000596399 / NM_001161748.2; = p.S149Ffs*59 on NM_030657.4) | Frame Shift Ins (INS) | VAF 172/429 reads (40%) | catalogued as rs1490674848; called by mutect2, varscan2
- LIPE | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751732396; called by muse, mutect2, varscan2
- LIPJ | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64245687; called by muse, varscan2
- LIX1L | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 16/506 reads (3%) | catalogued as rs376421123; called by muse, mutect2
- LOXL1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs368210432; called by muse, mutect2, varscan2
- LRP2 | c.12938C>A p.P4313H | Missense Mutation (SNP) | VAF 158/397 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99788740; called by muse, mutect2, varscan2
- LRP8 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147637344; called by muse, mutect2, varscan2
- LRRN3 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 48/182 reads (26%) | catalogued as rs1037509708, COSV57821426; called by muse, mutect2, varscan2
- LTB4R2 | c.743G>A p.R248Q (on ENST00000528054; = p.R217Q on NM_019839.5) | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs915617976; called by muse, mutect2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs752439249; called by mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs1383130845; called by mutect2, varscan2
- MATN4 | c.1592C>T p.A531V (on ENST00000372754; = p.A490V on NM_003833.4) | Missense Mutation (SNP) | VAF 55/413 reads (13%) | PolyPhen benign (0.19); catalogued as rs780167650; called by muse, mutect2, varscan2
- MEFV | c.1610+7C>T | Splice Region (SNP) | VAF 53/398 reads (13%) | catalogued as rs773383474; called by muse, mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 133/355 reads (37%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MEGF6 | c.3728C>T p.T1243M | Missense Mutation (SNP) | VAF 187/449 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs200310031; called by muse, mutect2, varscan2
- MEOX1 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.574); catalogued as rs867818350; called by muse, mutect2, varscan2
- MFSD2B | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs774723440, COSV57854537; called by muse, mutect2, varscan2
- MKI67 | c.5992C>T p.R1998* | Nonsense Mutation (SNP) | VAF 142/420 reads (34%) | catalogued as rs758152319, COSV64073711; called by muse, mutect2, varscan2
- MKS1 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 250/599 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs757310695, COSV56598488; called by muse, mutect2, varscan2
- MMP21 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64289764; called by muse, mutect2, varscan2
- MMP28 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 112/498 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs750488670; called by muse, mutect2, varscan2
- MRAP | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs766182053; called by muse, mutect2
- MRC2 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs767946605; called by muse, mutect2, varscan2
- MRPS14 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs375534115; called by muse, mutect2, varscan2
- MUS81 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 145/334 reads (43%) | catalogued as COSV57260331; called by muse, mutect2, varscan2
- NDUFS2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 59/549 reads (11%) | catalogued as COSV63488885; called by muse, mutect2, varscan2
- NEFH | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as rs1391677510; called by muse, mutect2, varscan2
- NES | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 68/265 reads (26%) | catalogued as rs148343241; called by muse, mutect2, varscan2
- NHLRC1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 69/648 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1291758138; called by muse, mutect2, varscan2
- NR2F6 | c.557T>G p.F186C | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV52244181; called by muse, mutect2, varscan2
- NRDC | c.616dup p.T206Nfs*3 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs747283256; called by mutect2, varscan2
- NSD2 | c.1798C>G p.R600G | Missense Mutation (SNP) | VAF 127/336 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56386050; called by muse, mutect2, varscan2
- NTF3 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV58417648; called by muse, mutect2, varscan2
- OBSCN | c.6916C>T p.R2306C | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770652160, COSV104372328; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 115/307 reads (37%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OPRPN | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV68193426; called by muse, mutect2
- OPRPN | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.149); catalogued as rs1258102334; called by mutect2, varscan2
- OR2H2 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as rs986756293; called by muse, mutect2, varscan2
- OTOF | c.4490A>G p.Y1497C (on ENST00000272371 / NM_194248.3; = p.Y730C on NM_004802.4) | Missense Mutation (SNP) | VAF 54/895 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402084278; called by muse, mutect2
- PARP10 | c.606del p.L204Wfs*38 | Frame Shift Del (DEL) | VAF 84/205 reads (41%) | catalogued as rs782379603; called by mutect2, varscan2
- PARVB | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200342928; called by muse, mutect2, varscan2
- PAXBP1 | c.2268-7del | Splice Region (DEL) | VAF 10/30 reads (33%) | catalogued as rs762331368; called by mutect2, varscan2
- PDPK1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.076); catalogued as rs965288790; called by mutect2, varscan2
- PDZD7 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 90/589 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757413778, COSV64647641; called by muse, mutect2, varscan2
- PIH1D1 | c.743del p.G248Afs*8 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | catalogued as rs1274833333; called by mutect2, pindel, varscan2
- PIK3R1 | c.1748_1750del p.X583_splice (on ENST00000521381 / NM_181523.3; = p.X313_splice on NM_181504.4) | Splice Site (DEL) | VAF 100/262 reads (38%) | catalogued as rs1131692243; called by pindel, varscan2
- PLCB2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 109/315 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs749786634, COSV99542912; called by muse, mutect2, varscan2
- PLEC | c.10856G>A p.R3619H (on ENST00000322810 / NM_201380.4; = p.R3509H on NM_000445.5) | Missense Mutation (SNP) | VAF 173/391 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs548876454, COSV59603009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2L | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV58991320; called by muse, mutect2, varscan2
- PON1 | c.1034_1035del p.T345Sfs*9 | Frame Shift Del (DEL) | VAF 136/628 reads (22%) | catalogued as rs779104502; called by pindel, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 57/326 reads (17%) | catalogued as rs775721804; called by mutect2, pindel, varscan2
- PPARA | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 230/535 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs559996245, COSV53078561; called by muse, mutect2, varscan2
- PPP2R3B | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1049762471; called by muse, mutect2, varscan2
- PPP6R3 | c.1385C>T p.T462M (on ENST00000393800 / NM_001352375.2; = p.T411M on NM_018312.5) | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761519919, COSV55723691; called by muse, mutect2, varscan2
- PRKD3 | c.1173-3del | Splice Region (DEL) | VAF 24/134 reads (18%) | catalogued as rs1424213306; called by mutect2, pindel
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 40/442 reads (9%) | catalogued as COSV99194092; called by mutect2, pindel
- PTPRD | c.4779C>G p.N1593K | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372535276; called by muse, mutect2
- PTPRK | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.074); catalogued as rs746682312; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | catalogued as rs759247453; called by mutect2, pindel*, varscan2
- RILPL1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1489251410, COSV61552674; called by muse, mutect2, varscan2
- RING1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs758793149; called by muse, mutect2, varscan2
- RP1L1 | c.4945G>A p.E1649K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as rs745521863, COSV66759557; called by muse, mutect2
- RPGRIP1L | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs902687917; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 21/527 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2
- SBF2 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as rs138612196, COSV56311522; ClinVar: uncertain significance; called by muse, mutect2
- SCAF4 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1399549475; called by muse, mutect2, varscan2
- SFSWAP | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99905955; called by muse, mutect2
- SFSWAP | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.108); catalogued as rs769428203; called by muse, mutect2
- SHANK3 | c.4327G>A p.A1443T | Missense Mutation (SNP) | VAF 91/180 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs749920586, COSV99438349; called by muse, mutect2, varscan2
- SHB | c.59dup p.Q21Afs*225 | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | catalogued as rs1385254953; called by pindel, varscan2*
- SLC37A4 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 264/589 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as rs754982680, COSV100421483; called by muse, mutect2, varscan2
- SLC39A13 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 205/481 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs769128330; called by muse, mutect2, varscan2
- SLIT2 | c.3901G>A p.G1301R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.563); catalogued as rs751793597, COSV56565732; called by muse, mutect2, varscan2
- SMPD4 | c.2410C>T p.R804C (on ENST00000409031 / NM_017951.4; = p.R775C on NM_017751.4) | Missense Mutation (SNP) | VAF 142/353 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); catalogued as rs752243342; called by muse, mutect2, varscan2
- SORCS2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs754337600, COSV61179468; called by muse, mutect2, varscan2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, mutect2, varscan2
- STXBP6 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs754315802, COSV60598050; called by muse, mutect2, varscan2
- SULF1 | c.623G>T p.R208I | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99484229; called by muse, mutect2, varscan2
- SUPT16H | c.1178del p.K393Sfs*29 | Frame Shift Del (DEL) | VAF 77/241 reads (32%) | catalogued as COSV53526696; called by mutect2, pindel, varscan2
- TACR1 | c.585-1G>T p.X195_splice | Splice Site (SNP) | VAF 34/315 reads (11%) | catalogued as COSV100538224; called by muse, mutect2, varscan2
- TANGO6 | c.3266_3268del p.K1089del | In Frame Del (DEL) | VAF 42/124 reads (34%) | catalogued as rs1286709290; called by pindel, varscan2
- TBC1D22A | c.96dup p.F33Lfs*2 | Frame Shift Ins (INS) | VAF 74/320 reads (23%) | catalogued as rs771822190; called by mutect2, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs757209781; called by mutect2, pindel, varscan2
- TCEAL4 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV65463446; called by muse, mutect2
- TENM4 | c.6847C>T p.R2283W | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs201369626, COSV53661523; called by muse, mutect2, varscan2
- TET2 | c.5641C>T p.H1881Y | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1169709175, COSV54399037; called by muse, mutect2
- TFAP2E | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1477198023; called by muse, mutect2
- THBS3 | c.2745del p.R916Vfs*12 | Frame Shift Del (DEL) | VAF 122/530 reads (23%) | catalogued as rs1355720789; called by mutect2, pindel, varscan2
- TMC8 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1168633691; called by muse, mutect2, varscan2
- TMEM150B | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs747179844; called by muse, varscan2
- TMEM196 | c.192del p.K64Nfs*6 | Frame Shift Del (DEL) | VAF 58/194 reads (30%) | catalogued as rs759398828; called by mutect2, varscan2
- TMPRSS7 | c.376C>T p.R126* (on ENST00000452346; = p.R14* on NM_001042575.2) | Nonsense Mutation (SNP) | VAF 90/226 reads (40%) | catalogued as rs1287242675; called by muse, mutect2, varscan2
- TOGARAM1 | c.502del p.E168Rfs*11 | Frame Shift Del (DEL) | VAF 75/233 reads (32%) | catalogued as COSV61887381; called by mutect2, pindel, varscan2
- TPTE | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751216471; called by muse, varscan2
- TRAF2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201857326; called by muse, mutect2
- TRAPPC11 | c.2942A>G p.H981R | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1554011266; ClinVar: uncertain significance; called by muse, mutect2
- TRIM65 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.719); catalogued as rs150634668; called by muse, mutect2, varscan2
- TRMT1 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs574964671; called by muse, mutect2, varscan2
- TTC23 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs957011890; called by muse, mutect2
- TTN | c.88382A>G p.Y29461C (on ENST00000591111; = p.Y22037C on NM_003319.4) | Missense Mutation (SNP) | VAF 33/288 reads (11%) | PolyPhen benign (0.006); catalogued as rs374084427; called by muse, mutect2, varscan2
- TUBGCP4 | c.1820G>A p.R607H (on ENST00000260383 / NM_001286414.3; = p.R606H on NM_014444.5) | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.835); catalogued as rs769082991; called by muse, mutect2, varscan2
- USP26 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs185719820, COSV63708863; called by muse, mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1554609756; called by mutect2, pindel, varscan2
- WWOX | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs371392600; called by muse, mutect2, varscan2
- XKR3 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV58885745; called by muse, mutect2, varscan2
- YIF1A | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780536897, COSV59174028; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 110/221 reads (50%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF480 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780025640, COSV57994533; called by muse, mutect2, varscan2
- ZNF555 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 84/389 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs866819298; called by muse, mutect2, varscan2
- ZNF579 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.692); catalogued as COSV57638336; called by muse, mutect2, varscan2
- ZNF668 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759082830, COSV100336741; called by muse, mutect2, varscan2
- ZNF710 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 124/273 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746977833; called by muse, mutect2, varscan2
- ZNF835 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 181/477 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554151224, COSV73379284, COSV73379521; called by muse, mutect2, varscan2
- AASS | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 152/642 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA5 | c.3728del p.F1243Sfs*31 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- ACAP2 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACAT2 | c.510dup p.W171Mfs*5 | Frame Shift Ins (INS) | VAF 34/139 reads (24%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2825G>T p.G942V | Missense Mutation (SNP) | VAF 122/484 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRB1 | c.730T>A p.Y244N | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AFF2 | c.1158T>G p.F386L | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AGTPBP1 | c.3220A>T p.S1074C (on ENST00000357081 / NM_001330701.2; = p.S1034C on NM_015239.2) | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AKAP9 | c.8458C>T p.Q2820* (on ENST00000359028; = p.Q2796* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/463 reads (9%) | called by muse, mutect2
- ANKRD18B | c.2318G>A p.C773Y | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD60 | c.234_235del p.C78* | Nonsense Mutation (DEL) | VAF 60/370 reads (16%) | called by pindel, varscan2
- APC | c.4692_4695del p.D1565Ifs*10 | Frame Shift Del (DEL) | VAF 101/268 reads (38%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.2923C>T p.Q975* (on ENST00000359920 / NM_001130955.2; = p.Q871* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 66/538 reads (12%) | called by muse, mutect2, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, varscan2
- ATM | c.3142del p.T1048Lfs*16 | Frame Shift Del (DEL) | VAF 134/377 reads (36%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.1189A>T p.I397F | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- ATP6V1G1 | c.96G>C p.R32S | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- BANK1 | c.829_833del p.I277Vfs*25 | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- BTG3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- C15orf39 | c.2052del p.T685Hfs*17 | Frame Shift Del (DEL) | VAF 106/269 reads (39%) | called by mutect2, pindel, varscan2
- C17orf75 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C5orf34 | c.1312del p.M438Wfs*5 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- C6orf15 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CACNB2 | c.1418dup p.N473Kfs*5 (on ENST00000324631 / NM_201596.3; = p.N418Kfs*5 on NM_000724.4) | Frame Shift Ins (INS) | VAF 94/383 reads (25%) | called by mutect2, pindel, varscan2
- CAMK1D | c.922-1G>A p.X308_splice | Splice Site (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- CAMK1D | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 47/510 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); called by muse, mutect2
- CAMSAP1 | c.3533_3555del p.R1178Qfs*50 | Frame Shift Del (DEL) | VAF 40/208 reads (19%) | called by mutect2, pindel, varscan2
- CANX | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CAPRIN1 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- CBFA2T3 | c.234del p.S79Afs*41 | Frame Shift Del (DEL) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- CBX6 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC17 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPB | c.5005-1G>A p.X1669_splice | Splice Site (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2
- CDX1 | c.98del p.P33Rfs*166 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | called by mutect2, varscan2
- CEP131 | c.3029C>T p.A1010V (on ENST00000269392 / NM_001319228.2; = p.A1007V on NM_014984.4) | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CFAP91 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFP | c.967del p.E323Sfs*10 | Frame Shift Del (DEL) | VAF 44/246 reads (18%) | called by mutect2, varscan2
- CHAF1A | c.1235A>C p.Q412P | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHCHD6 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CIITA | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLDN19 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.5763A>C p.K1921N | Missense Mutation (SNP) | VAF 213/517 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COX7C | c.74del p.K25Rfs*14 | Frame Shift Del (DEL) | VAF 26/206 reads (13%) | called by mutect2, pindel, varscan2
- CRB2 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD2 | c.3234del p.C1079Afs*38 | Frame Shift Del (DEL) | VAF 92/244 reads (38%) | called by mutect2, pindel, varscan2
- CSRNP1 | c.1495T>G p.L499V | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CYP2E1 | c.713del p.N238Mfs*5 | Frame Shift Del (DEL) | VAF 20/141 reads (14%) | called by mutect2, pindel, varscan2
- DBH | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- DCAF12L1 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 90/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 128/338 reads (38%) | called by mutect2, varscan2
- DDX60L | c.3506del p.P1169Qfs*24 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- DENND4A | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH14 | c.7675del p.I2559Lfs*5 (on ENST00000445597; = p.I3331Lfs*5 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 86/318 reads (27%) | called by mutect2, varscan2
- DNAJC8 | c.666C>A p.S222R | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DOCK2 | c.4148C>A p.P1383H | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- DSP | c.5072A>G p.D1691G | Missense Mutation (SNP) | VAF 254/565 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- EME1 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ENOX1 | c.1891del p.R631Dfs*27 | Frame Shift Del (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- EOGT | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHA1 | c.2037G>T p.Q679H | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERMARD | c.1163A>C p.N388T | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EVL | c.136A>G p.T46A (on ENST00000402714 / NM_001330221.2; = p.T48A on NM_016337.3) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EVPL | c.5453_5454del p.L1818Rfs*4 | Frame Shift Del (DEL) | VAF 52/162 reads (32%) | called by pindel, varscan2
- FBN2 | c.2384G>A p.C795Y | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 149/347 reads (43%) | called by mutect2, varscan2
- FEN1 | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FILIP1L | c.1508A>T p.E503V (on ENST00000354552 / NM_182909.3; = p.E263V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLRT2 | c.1714T>C p.Y572H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FOLR3 | c.598A>G p.S200G | Missense Mutation (SNP) | VAF 131/505 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FOXC2 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 156/897 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMD4B | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FTO | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- GABRG3 | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- GAS8 | c.543A>T p.Q181H | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- GCKR | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 42/744 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- GHITM | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GLDN | c.1114T>G p.C372G | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GOLGA4 | c.5970C>A p.H1990Q | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GPATCH1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPR52 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GTF3C1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 151/367 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H4C2 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAS2 | c.1231T>G p.L411V | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- HCFC2 | c.1857A>C p.K619N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HOOK2 | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTT | c.8582T>C p.V2861A | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- IARS2 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- IDH2 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.099); called by muse, mutect2
- IDO2 | c.240G>T p.Q80H (on ENST00000389060; = p.Q93H on NM_194294.2) | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- IGFL4 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IHH | c.630dup p.R211Tfs*71 | Frame Shift Ins (INS) | VAF 102/300 reads (34%) | called by mutect2, pindel, varscan2
- INSYN2A | c.1409del p.K470Sfs*64 | Frame Shift Del (DEL) | VAF 24/218 reads (11%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.29_34del p.A10_R12delinsG | In Frame Del (DEL) | VAF 181/382 reads (47%) | called by pindel, varscan2
- IVD | c.1220C>A p.A407D (on ENST00000651168; = p.A404D on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 210/465 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- JPH2 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK2 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNC3 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 115/646 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KCNH8 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 10/275 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2
- KIF14 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- KLHL26 | c.103del p.A35Pfs*33 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel
- KMT2D | c.7593del p.S2532Lfs*11 | Frame Shift Del (DEL) | VAF 69/181 reads (38%) | called by mutect2, pindel, varscan2
- KNG1 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LAMB3 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 105/335 reads (31%) | called by muse, mutect2, varscan2
- LEMD3 | c.2378A>G p.D793G | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- LRCOL1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- LRRTM4 | c.1135dup p.Q379Pfs*8 | Frame Shift Ins (INS) | VAF 53/322 reads (16%) | called by mutect2, pindel, varscan2
- LRSAM1 | c.1210A>C p.M404L | Missense Mutation (SNP) | VAF 191/472 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K6 | c.2138G>A p.S713N | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAP4K3 | c.781dup p.R261Kfs*5 | Frame Shift Ins (INS) | VAF 51/186 reads (27%) | called by mutect2, varscan2
- MAPK8IP3 | c.1760del p.P587Lfs*10 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- MEIS3 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MLXIP | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MMS19 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MOGAT3 | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MUC16 | c.20291C>T p.T6764I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MYOD1 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAM2 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NRXN1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NSD2 | c.1268_1270del p.P423del | In Frame Del (DEL) | VAF 72/199 reads (36%) | called by pindel, varscan2
- NSD3 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- NUDT22 | c.771+3G>A | Splice Region (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- NUP153 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR1J1 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OR2J3 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- OS9 | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2
- P2RX3 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2
- PAX6 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 46/678 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.037); called by muse, mutect2
- PCDH8 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCMTD2 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PDCD1 | c.105del p.T36Pfs*9 | Frame Shift Del (DEL) | VAF 44/203 reads (22%) | called by mutect2, pindel, varscan2
- PDZD8 | c.1041C>A p.C347* | Nonsense Mutation (SNP) | VAF 93/335 reads (28%) | called by muse, mutect2, varscan2
- PES1 | c.193dup p.Y65Lfs*20 | Frame Shift Ins (INS) | VAF 61/266 reads (23%) | called by mutect2, pindel, varscan2
- PINK1 | c.1738G>C p.A580P | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- PKD1 | c.6784G>A p.G2262S | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCG1 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PLPPR1 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- POR | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PPP1R2C | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 183/406 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PPP1R3B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PPP2R5A | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PRAG1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRPS2 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR14L | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.322); called by muse, mutect2
- PRR5-ARHGAP8 | c.787A>C p.S263R (on ENST00000352766; = p.S140R on NM_181334.5) | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- PSME1 | c.608A>C p.E203A | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PTBP1 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- RANBP2 | c.1530T>G p.Y510* | Nonsense Mutation (SNP) | VAF 150/495 reads (30%) | called by muse, mutect2, varscan2
- RGS7 | c.1399T>C p.F467L | Missense Mutation (SNP) | VAF 145/508 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RNF167 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RNF20 | c.2789del p.K930Rfs*17 | Frame Shift Del (DEL) | VAF 52/124 reads (42%) | called by mutect2, varscan2
- RNF213 | c.5833C>A p.Q1945K | Missense Mutation (SNP) | VAF 173/364 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RRBP1 | c.902del p.K301Rfs*2 | Frame Shift Del (DEL) | VAF 55/232 reads (24%) | called by pindel, varscan2
- SALL4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SAV1 | c.950+2T>C p.X317_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- SCRT1 | c.117G>T p.G39= | Splice Region (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- SDK1 | c.4002C>A p.H1334Q | Missense Mutation (SNP) | VAF 96/732 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SEMA4D | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SHANK1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SHC1 | c.1559A>T p.Y520F (on ENST00000368445 / NM_183001.5; = p.Y411F on NM_003029.5) | Missense Mutation (SNP) | VAF 135/413 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SIRPA | c.560del p.N187Mfs*15 | Frame Shift Del (DEL) | VAF 166/640 reads (26%) | called by mutect2, pindel, varscan2
- SLC10A7 | c.43G>T p.G15* | Nonsense Mutation (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- SLC16A8 | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A39 | c.882A>G p.R294= (on ENST00000377095 / NM_001143780.3; = p.R286= on NM_016016.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- SLC26A1 | c.992A>G p.Q331R | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2
- SLC6A18 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLF2 | c.1356del p.A453Lfs*34 | Frame Shift Del (DEL) | VAF 36/258 reads (14%) | called by mutect2, pindel, varscan2
- SMARCA5 | c.270T>A p.N90K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMC1A | c.2749A>C p.T917P | Missense Mutation (SNP) | VAF 175/421 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SMCHD1 | c.5898G>C p.K1966N | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SMG5 | c.18del p.T7Qfs*49 | Frame Shift Del (DEL) | VAF 73/256 reads (29%) | called by mutect2, varscan2
- SNW1 | c.1520_1522del p.E507del | In Frame Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- SOBP | c.1388del p.P463Rfs*31 | Frame Shift Del (DEL) | VAF 61/167 reads (37%) | called by mutect2, pindel, varscan2
- SPECC1L | c.883A>C p.S295R | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SPEN | c.1726A>G p.K576E | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.4281A>C p.Q1427H | Missense Mutation (SNP) | VAF 183/436 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTBN5 | c.9139_9140del p.D3047Pfs*101 | Frame Shift Del (DEL) | VAF 141/423 reads (33%) | called by pindel, varscan2
- SRBD1 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 119/419 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SRSF6 | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 114/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SSR1 | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STAMBPL1 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STPG4 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 113/401 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STRIP1 | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYCE1 | c.253C>T p.Q85* (on ENST00000343131 / NM_001143764.3; = p.Q49* on NM_130784.3) | Nonsense Mutation (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
- SYNE1 | c.13690A>G p.R4564G (on ENST00000367255 / NM_182961.4; = p.R4493G on NM_033071.3) | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TAF1 | c.2436del p.A813Pfs*14 (on ENST00000373790 / NM_138923.4; = p.A834Pfs*14 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 84/204 reads (41%) | called by mutect2, varscan2
- TCF12 | c.1763_1779del p.L588* | Frame Shift Del (DEL) | VAF 135/421 reads (32%) | called by mutect2, pindel, varscan2
- TEAD2 | c.1246_1247del p.D416Hfs*65 | Frame Shift Del (DEL) | VAF 110/311 reads (35%) | called by pindel, varscan2
- TEX13C | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TEX14 | c.3891del p.S1298Afs*22 (on ENST00000240361 / NM_001201457.2; = p.S1252Afs*22 on NM_031272.5) | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- TLCD1 | c.227T>A p.I76N | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- TLE1 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM63C | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TNC | c.6325A>G p.T2109A | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM26 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2
- TRPM6 | c.3895dup p.A1299Gfs*4 | Frame Shift Ins (INS) | VAF 163/511 reads (32%) | called by mutect2, pindel, varscan2
- TSC1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2
- TSHZ2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUBA1C | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 238/597 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- USP2 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- USP28 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- VNN1 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR70 | c.229_230del p.N77* | Frame Shift Del (DEL) | VAF 55/175 reads (31%) | called by mutect2, pindel, varscan2
- WFIKKN1 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNK3 | c.4301C>T p.T1434I | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- WNT3A | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWC3 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- YARS1 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 17/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZDHHC11B | c.714G>C p.M238I | Missense Mutation (SNP) | VAF 23/475 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- ZMYM3 | c.3626T>C p.L1209P | Missense Mutation (SNP) | VAF 180/434 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF112 | c.969_970del p.R323Sfs*12 (on ENST00000337401 / NM_001083335.2; = p.R317Sfs*12 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | called by pindel, varscan2
- ZNF140 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF444 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF445 | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF589 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN21 | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, varscan2
- ABCC12 | c.1845C>T p.R615= | Silent (SNP) | VAF 118/289 reads (41%) | catalogued as rs762941970, COSV100252505; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCC3 | c.126C>T p.C42= | Silent (SNP) | VAF 121/293 reads (41%) | called by muse, mutect2, varscan2
- ABCC8 | c.4737A>G p.A1579= | Silent (SNP) | VAF 234/533 reads (44%) | called by muse, mutect2, varscan2
- ACBD4 | c.621G>A p.P207= (on ENST00000376955 / NM_001378111.1; = p.V211M on NM_024722.4) | Silent (SNP) | VAF 116/253 reads (46%) | catalogued as rs200905184; called by muse, mutect2, varscan2
- ACOT12 | c.54G>A p.A18= | Silent (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- ACTN4 | c.1509C>T p.D503= | Silent (SNP) | VAF 233/579 reads (40%) | catalogued as rs750084549, COSV53148297, COSV99399956; called by muse, mutect2, varscan2
- ADARB2 | c.249G>A p.P83= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs755493645; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.585G>A p.S195= | Silent (SNP) | VAF 84/265 reads (32%) | catalogued as rs1184308352, COSV58446469, COSV58446644; called by muse, mutect2, varscan2
- AHCTF1 | c.5457A>G p.E1819= (on ENST00000366508; = p.E1793= on NM_015446.5) | Silent (SNP) | VAF 111/400 reads (28%) | called by muse, mutect2, varscan2
- AKAP9 | c.78G>A p.Q26= | Silent (SNP) | VAF 129/442 reads (29%) | catalogued as rs1030567089; called by muse, mutect2, varscan2
- AMPH | c.1680T>C p.T560= | Silent (SNP) | VAF 75/322 reads (23%) | called by muse, mutect2, varscan2
- ANKH | c.159G>A p.G53= | Silent (SNP) | VAF 111/449 reads (25%) | called by muse, mutect2, varscan2
- ANKRD27 | c.534G>A p.A178= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as rs765125690, COSV60136352; called by muse, mutect2, varscan2
- ANP32E | c.270T>C p.L90= | Silent (SNP) | VAF 68/237 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.2445C>T p.D815= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs994846799, COSV55229848; called by muse, mutect2, varscan2
- ARRB1 | c.393G>A p.P131= | Silent (SNP) | VAF 100/224 reads (45%) | catalogued as rs867934311, COSV100758037, COSV63578126; called by muse, mutect2, varscan2
- ATP11A | c.1308C>T p.Y436= | Silent (SNP) | VAF 101/231 reads (44%) | catalogued as rs565434530, COSV52105735; called by muse, mutect2, varscan2
- B3GNT6 | c.498G>A p.A166= | Silent (SNP) | VAF 148/277 reads (53%) | catalogued as COSV62828068; called by muse, mutect2, varscan2
- BACE2 | c.9A>G p.A3= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- BCL9 | c.2340C>A p.G780= | Silent (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- BICDL2 | c.30G>A p.P10= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs372212421, COSV66369943; called by muse, mutect2
- BICRAL | c.318T>G p.L106= | Silent (SNP) | VAF 142/324 reads (44%) | called by muse, mutect2, varscan2
- CAMK1 | c.579G>A p.K193= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs1262870375; called by muse, mutect2, varscan2
- CASK | c.1857A>C p.A619= | Silent (SNP) | VAF 143/343 reads (42%) | called by muse, mutect2, varscan2
- CAV1 | c.171A>G p.K57= | Silent (SNP) | VAF 182/624 reads (29%) | called by muse, mutect2, varscan2
- CCR6 | c.1110G>A p.S370= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as rs773654249, COSV59475235, COSV59476537; called by muse, mutect2, varscan2
- CD163L1 | c.939C>T p.G313= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as rs201378543; called by muse, mutect2, varscan2
- CFTR | c.4251A>G p.E1417= | Silent (SNP) | VAF 33/615 reads (5%) | catalogued as CD930931; called by muse, mutect2
- CPPED1 | c.603C>T p.I201= | Silent (SNP) | VAF 139/382 reads (36%) | catalogued as rs749114972; called by muse, mutect2, varscan2
- CSMD1 | c.901C>A p.R301= | Silent (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- CXCL6 | c.90G>A p.P30= | Silent (SNP) | VAF 25/276 reads (9%) | catalogued as rs754627748, COSV56903630; called by muse, mutect2
- CYFIP1 | c.1095C>T p.R365= | Silent (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- CYP24A1 | c.52C>T p.L18= | Silent (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- CYP2A13 | c.18G>T p.L6= | Silent (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2
- CYP4F22 | c.1401C>A p.P467= | Silent (SNP) | VAF 19/558 reads (3%) | called by muse, mutect2
- DAB2IP | c.1089C>T p.L363= (on ENST00000408936; = p.L335= on NM_032552.3) | Silent (SNP) | VAF 75/162 reads (46%) | catalogued as rs1218247667, COSV52262959; called by muse, mutect2, varscan2
- DHCR24 | c.1359C>T p.C453= | Silent (SNP) | VAF 195/482 reads (40%) | called by muse, mutect2, varscan2
- DNAH10 | c.11115G>A p.L3705= (on ENST00000409039; = p.L3644= on NM_207437.3) | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- DNAH7 | c.9954C>T p.N3318= | Silent (SNP) | VAF 9/263 reads (3%) | called by muse, mutect2
- DNAH8 | c.7023C>A p.S2341= | Silent (SNP) | VAF 117/248 reads (47%) | called by muse, mutect2, varscan2
- DNAJC12 | c.201C>A p.T67= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- DNMT3B | c.948C>A p.T316= | Silent (SNP) | VAF 233/585 reads (40%) | called by muse, mutect2, varscan2
- DOCK10 | c.2889A>G p.V963= | Silent (SNP) | VAF 74/172 reads (43%) | called by muse, mutect2, varscan2
- DRD5 | c.1158G>T p.T386= | Silent (SNP) | VAF 27/267 reads (10%) | called by muse, mutect2
- DSCAML1 | c.3396T>C p.A1132= (on ENST00000321322; = p.A1072= on NM_020693.4) | Silent (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- DYSF | c.1404C>T p.R468= | Silent (SNP) | VAF 27/692 reads (4%) | called by muse, mutect2
- EEPD1 | c.36C>A p.P12= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- EFCC1 | c.1723C>T p.L575= | Silent (SNP) | VAF 21/278 reads (8%) | catalogued as rs1454748940, COSV101460037; called by muse, mutect2
- EMILIN3 | c.922C>T p.L308= | Silent (SNP) | VAF 51/289 reads (18%) | called by muse, mutect2, varscan2
- ENGASE | c.474C>T p.I158= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as rs201681138; called by muse, mutect2, varscan2
- ENPP7 | c.630G>A p.P210= | Silent (SNP) | VAF 42/509 reads (8%) | catalogued as rs146147882; called by muse, mutect2
- ERVV-2 | c.546C>T p.R182= | Silent (SNP) | VAF 156/546 reads (29%) | called by muse, mutect2, varscan2
- EVX2 | c.1266T>C p.G422= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1468525457; called by muse, mutect2, varscan2
- EXO5 | c.763C>T p.L255= | Silent (SNP) | VAF 73/187 reads (39%) | called by muse, mutect2, varscan2
- EXOC7 | c.241C>T p.L81= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV100135597; called by muse, mutect2, varscan2
- F2 | c.1158C>A p.P386= | Silent (SNP) | VAF 21/348 reads (6%) | called by muse, mutect2
- FLT4 | c.1503C>T p.I501= | Silent (SNP) | VAF 227/567 reads (40%) | catalogued as rs745882315, COSV56106457; called by muse, mutect2, varscan2
- FOXE1 | c.120G>A p.A40= | Silent (SNP) | VAF 81/125 reads (65%) | catalogued as rs760222007; called by muse, mutect2, varscan2
- FSIP2 | c.6516G>A p.T2172= | Silent (SNP) | VAF 15/270 reads (6%) | catalogued as rs1319585108; called by muse, mutect2
- GAA | c.1593C>T p.D531= | Silent (SNP) | VAF 63/538 reads (12%) | catalogued as rs138732016; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GALK1 | c.261G>A p.R87= | Silent (SNP) | VAF 141/274 reads (51%) | called by muse, mutect2, varscan2
- GDF7 | c.1065C>T p.H355= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as rs1380262246; called by muse, mutect2
- GFER | c.558C>T p.F186= | Silent (SNP) | VAF 32/690 reads (5%) | catalogued as rs142220504, COSV50191473; called by muse, mutect2
- GLIS3 | c.1623C>A p.T541= | Silent (SNP) | VAF 34/434 reads (8%) | called by muse, mutect2
- GLRA2 | c.147C>T p.D49= | Silent (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- GPHA2 | c.315G>A p.G105= | Silent (SNP) | VAF 141/396 reads (36%) | called by muse, mutect2, varscan2
- HEPACAM | c.1233G>A p.P411= | Silent (SNP) | VAF 14/383 reads (4%) | catalogued as rs937453909; called by muse, mutect2
- HSD11B1L | c.687G>A p.P229= | Silent (SNP) | VAF 15/290 reads (5%) | catalogued as rs1410514565, COSV100028605; called by muse, mutect2
- IPO9 | c.1537C>T p.L513= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as rs780528212; called by muse, mutect2, varscan2
- JAK2 | c.954C>T p.C318= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as rs1480230972, COSV67644219; called by muse, mutect2, varscan2
- KDM6A | c.1338T>C p.S446= | Silent (SNP) | VAF 86/205 reads (42%) | catalogued as rs764454979; called by muse, mutect2, varscan2
- KDR | c.3498T>C p.A1166= | Silent (SNP) | VAF 65/506 reads (13%) | called by muse, mutect2, varscan2
- KIAA1210 | c.546C>T p.A182= | Silent (SNP) | VAF 93/246 reads (38%) | catalogued as rs773245380, COSV68177584; called by muse, mutect2, varscan2
- KLF14 | c.744G>A p.T248= | Silent (SNP) | VAF 24/594 reads (4%) | catalogued as rs1380066667, COSV100205915; called by muse, mutect2
- KLHL22 | c.741G>A p.P247= | Silent (SNP) | VAF 45/283 reads (16%) | catalogued as rs777894285; called by muse, mutect2, varscan2
- KLRD1 | c.519C>A p.I173= | Silent (SNP) | VAF 61/247 reads (25%) | catalogued as COSV100282279; called by muse, mutect2, varscan2
- KRTAP19-1 | c.99C>T p.C33= | Silent (SNP) | VAF 38/552 reads (7%) | catalogued as COSV66861536; called by muse, mutect2
- LRRC45 | c.1443C>T p.G481= | Silent (SNP) | VAF 16/462 reads (3%) | called by muse, mutect2
- LSP1 | c.297C>T p.G99= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs567986256, COSV100289641; called by muse, mutect2, varscan2
- LTN1 | c.5112C>T p.N1704= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1395885354, COSV63733033; called by muse, mutect2, varscan2
- LUZP4 | c.177G>A p.S59= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs921897848; called by muse, mutect2, varscan2
- MAML2 | c.2865A>G p.V955= | Silent (SNP) | VAF 111/266 reads (42%) | called by muse, mutect2, varscan2
- MARCHF3 | c.753A>G p.T251= | Silent (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- MEGF9 | c.1182C>T p.D394= | Silent (SNP) | VAF 26/392 reads (7%) | catalogued as rs1348426162; called by muse, mutect2
- MELTF | c.855C>T p.A285= | Silent (SNP) | VAF 13/447 reads (3%) | catalogued as rs1296525280; called by muse, mutect2
- MKLN1 | c.228T>C p.Y76= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs760934226; called by muse, mutect2, varscan2
- MLYCD | c.690C>T p.R230= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as rs1218299029, COSV99299253; called by muse, mutect2, varscan2
- MRAS | c.522A>T p.V174= | Silent (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- MUC2 | c.2721C>A p.S907= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- MXD4 | c.465A>C p.S155= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1273729344; called by muse, mutect2, varscan2
- MYH10 | c.5178G>A p.A1726= | Silent (SNP) | VAF 45/452 reads (10%) | catalogued as rs748885278; called by muse, mutect2, varscan2
- N4BP1 | c.1032A>G p.E344= | Silent (SNP) | VAF 66/157 reads (42%) | called by muse, mutect2, varscan2
- NAIP | c.246G>A p.A82= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs768947830; called by muse, mutect2
- NCF1 | c.501C>T p.Y167= | Silent (SNP) | VAF 123/845 reads (15%) | catalogued as rs782496561, COSV99194361; called by muse, mutect2, varscan2
- NEFH | c.1173C>G p.V391= | Silent (SNP) | VAF 218/487 reads (45%) | called by muse, mutect2
- NOS1 | c.1285C>T p.L429= | Silent (SNP) | VAF 57/197 reads (29%) | catalogued as COSV100500278; called by muse, mutect2, varscan2
- NSD3 | c.2730G>A p.S910= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs763241267, COSV57668215; called by muse, mutect2, varscan2
- OR6X1 | c.663C>T p.S221= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs759293628, COSV100020490; called by muse, mutect2, varscan2
- OSTC | c.228C>A p.A76= | Silent (SNP) | VAF 108/273 reads (40%) | called by muse, mutect2, varscan2
- PATZ1 | c.1491C>T p.C497= | Silent (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1809C>T p.N603= | Silent (SNP) | VAF 44/580 reads (8%) | catalogued as rs1554164817, COSV56518234; called by muse, mutect2
- PCDHA3 | c.363G>A p.V121= | Silent (SNP) | VAF 58/372 reads (16%) | called by muse, mutect2, varscan2
- PCDHA3 | c.969G>A p.T323= | Silent (SNP) | VAF 148/348 reads (43%) | catalogued as COSV100793231; called by muse, mutect2, varscan2
- PDE2A | c.1485C>T p.T495= | Silent (SNP) | VAF 130/284 reads (46%) | called by muse, mutect2, varscan2
- PDLIM4 | c.600C>T p.P200= | Silent (SNP) | VAF 92/343 reads (27%) | catalogued as rs754780133, COSV53805369, COSV53805403, COSV99516914; called by muse, mutect2, varscan2
- PDZRN4 | c.273G>A p.S91= | Silent (SNP) | VAF 73/195 reads (37%) | catalogued as rs757152985, COSV101284559; called by muse, mutect2, varscan2
- PGPEP1 | c.382C>A p.R128= | Silent (SNP) | VAF 147/360 reads (41%) | catalogued as COSV53252801; called by muse, mutect2, varscan2
- PGS1 | c.687C>T p.S229= | Silent (SNP) | VAF 78/176 reads (44%) | catalogued as rs751549914, COSV99428516; called by muse, mutect2, varscan2
- PI16 | c.918C>T p.T306= | Silent (SNP) | VAF 84/313 reads (27%) | called by muse, mutect2, varscan2
- PIK3C2A | c.2118A>G p.K706= | Silent (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- PLCH1 | c.1134G>A p.K378= (on ENST00000340059 / NM_001130960.2; = p.K390= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- POGK | c.1039C>T p.L347= | Silent (SNP) | VAF 123/412 reads (30%) | called by muse, mutect2, varscan2
- POLR2D | c.213C>T p.F71= | Silent (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2, varscan2
- PRAG1 | c.1434G>A p.A478= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs55800591; called by muse, mutect2, varscan2
- PRR23A | c.717C>T p.R239= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV101270358; called by muse, mutect2, varscan2
- PTCH2 | c.3384A>G p.P1128= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs754325658; called by muse, mutect2, varscan2
- RECQL4 | c.3348G>A p.P1116= | Silent (SNP) | VAF 33/223 reads (15%) | catalogued as rs368712314, COSV100020679; ClinVar: likely benign; called by muse, mutect2, varscan2
- RUNX2 | c.183G>A p.Q61= | Silent (SNP) | VAF 182/413 reads (44%) | called by muse, mutect2, varscan2
- SALL3 | c.117C>T p.S39= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs146469887; called by muse, mutect2, varscan2
- SALL3 | c.2505G>A p.S835= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as rs752107564; called by muse, mutect2, varscan2
- SEZ6L | c.1128C>T p.D376= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs371203903; called by muse, mutect2, varscan2
- SHANK1 | c.753G>A p.L251= | Silent (SNP) | VAF 71/320 reads (22%) | called by muse, mutect2, varscan2
- SIMC1 | c.1245C>T p.H415= (on ENST00000443967 / NM_001308196.1; = p.H434= on NM_001308195.2) | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as rs550354484; called by muse, mutect2, varscan2
- SLC15A3 | c.228G>A p.A76= | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2
- SLC19A3 | c.519C>T p.N173= | Silent (SNP) | VAF 117/288 reads (41%) | catalogued as rs765070607; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A6 | c.951C>T p.S317= | Silent (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
- SOHLH2 | c.474C>A p.P158= | Silent (SNP) | VAF 31/297 reads (10%) | called by muse, mutect2
- SPOCK1 | c.1014T>C p.N338= | Silent (SNP) | VAF 90/163 reads (55%) | catalogued as rs771232497; called by muse, mutect2, varscan2
- SSTR3 | c.1083C>T p.S361= | Silent (SNP) | VAF 121/290 reads (42%) | catalogued as rs1173180631; called by muse, mutect2, varscan2
- STAC | c.75G>T p.P25= | Silent (SNP) | VAF 86/258 reads (33%) | catalogued as COSV56211616; called by muse, mutect2, varscan2
- SYNJ1 | c.3501G>A p.P1167= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs758366163, COSV100449844; called by muse, mutect2, varscan2
- TBX20 | c.1332G>A p.T444= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as rs1194051605; called by muse, mutect2
- THSD1 | c.1731G>T p.P577= | Silent (SNP) | VAF 96/212 reads (45%) | called by muse, mutect2, varscan2
- TIGD2 | c.564A>G p.S188= | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- TMED4 | c.351T>C p.N117= | Silent (SNP) | VAF 153/504 reads (30%) | called by muse, mutect2, varscan2
- TMUB1 | c.159C>T p.S53= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs774561970, COSV104399612; called by muse, mutect2, varscan2
- TNS1 | c.3366G>A p.Q1122= | Silent (SNP) | VAF 164/437 reads (38%) | called by muse, mutect2, varscan2
- TOP3B | c.2205G>A p.V735= | Silent (SNP) | VAF 54/110 reads (49%) | called by mutect2, varscan2
- TRPT1 | c.453G>A p.T151= (on ENST00000317459 / NM_001160393.1; = p.T102= on NM_031472.4) | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs200750477, COSV54172106; called by muse, mutect2, varscan2
- TSC2 | c.4227G>A p.R1409= | Silent (SNP) | VAF 214/450 reads (48%) | catalogued as COSV51927197; called by muse, mutect2, varscan2
- TTN | c.47967C>A p.T15989= (on ENST00000591111; = p.T8565= on NM_003319.4) | Silent (SNP) | VAF 93/549 reads (17%) | called by muse, mutect2, varscan2
- UPF2 | c.411A>C p.R137= | Silent (SNP) | VAF 64/224 reads (29%) | called by muse, mutect2, varscan2
- USP7 | c.12G>A p.Q4= | Silent (SNP) | VAF 79/178 reads (44%) | catalogued as COSV61213958; called by muse, mutect2, varscan2
- VPS35 | c.813T>C p.P271= | Silent (SNP) | VAF 157/351 reads (45%) | called by muse, mutect2, varscan2
- XAB2 | c.2217C>T p.N739= | Silent (SNP) | VAF 160/430 reads (37%) | catalogued as rs1372600368; called by muse, mutect2, varscan2
- ZBTB10 | c.759C>T p.S253= | Silent (SNP) | VAF 118/364 reads (32%) | catalogued as rs769123081; called by muse, mutect2, varscan2
- ZNF304 | c.1140G>A p.Q380= | Silent (SNP) | VAF 100/269 reads (37%) | called by muse, mutect2, varscan2
- ZNF707 | c.870C>T p.C290= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs782506046; called by muse, mutect2, varscan2
- ZNHIT1 | c.414G>A p.V138= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as rs758439500; called by muse, mutect2, varscan2
- ZSCAN21 | c.309C>A p.A103= | Silent (SNP) | VAF 20/191 reads (10%) | called by muse, varscan2
- ZSCAN5A | c.480C>T p.D160= | Silent (SNP) | VAF 119/289 reads (41%) | catalogued as rs111907569; called by muse, mutect2, varscan2
- AC009237.3 | n.371del | RNA (DEL) | VAF 35/159 reads (22%) | called by mutect2, pindel, varscan2
- AC091163.2 | n.465T>C | RNA (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2
- AC244517.10 | c.36-9219G>A | Intron (SNP) | VAF 231/859 reads (27%) | catalogued as rs781882772, COSV73145193; called by muse, mutect2, varscan2
- AC245052.3 | chr19:54231775 T>C | 3'Flank (SNP) | VAF 73/266 reads (27%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 7/68 reads (10%) | catalogued as rs766264675; called by pindel, varscan2*
- ANXA8L1 | c.113-98G>A | Intron (SNP) | VAF 81/559 reads (14%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498892 C>A | 5'Flank (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-97del | Intron (DEL) | VAF 6/52 reads (12%) | catalogued as rs1231343254; called by mutect2, pindel, varscan2
- C10orf143 | c.69+3008dup | Intron (INS) | VAF 102/426 reads (24%) | catalogued as rs758369767; called by mutect2, varscan2
- C8orf82 | c.157-309C>T | Intron (SNP) | VAF 76/157 reads (48%) | called by muse, mutect2, varscan2
- CACNB4 | c.148-88177G>T | Intron (SNP) | VAF 54/331 reads (16%) | called by muse, mutect2, varscan2
- CACNG4 | c.*363dup | 3'UTR (INS) | VAF 119/346 reads (34%) | called by mutect2, pindel, varscan2
- CCDC6 | c.*122T>C | 3'UTR (SNP) | VAF 98/357 reads (27%) | catalogued as rs1056136582; called by muse, mutect2, varscan2
- CCNQP1 | n.28C>T | RNA (SNP) | VAF 86/571 reads (15%) | catalogued as rs568832052; called by muse, mutect2, varscan2
- CIBAR1 | c.658-1873C>T | Intron (SNP) | VAF 25/179 reads (14%) | catalogued as rs776710213; called by muse, mutect2, varscan2
- CLN6 | c.297+26_297+27del | Intron (DEL) | VAF 24/184 reads (13%) | catalogued as rs752943329; called by pindel, varscan2
- COL10A1 | c.-15-31C>T | Intron (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- COX11 | c.*1402G>A | 3'UTR (SNP) | VAF 47/197 reads (24%) | called by muse, mutect2, varscan2
- DAGLB | c.1141-212A>G | Intron (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2, varscan2
- DGKZ | c.933+98C>T | Intron (SNP) | VAF 55/187 reads (29%) | called by muse, mutect2, varscan2
- DGLUCY | c.1702-955C>T | Intron (SNP) | VAF 59/115 reads (51%) | catalogued as rs1279879470; called by muse, mutect2, varscan2
- DMTN | c.*848G>C | 3'UTR (SNP) | VAF 40/87 reads (46%) | catalogued as rs541120046; called by muse, mutect2
- EHBP1L1 | c.4284-27del | Intron (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- GATD1 | c.544+48del | Intron (DEL) | VAF 53/140 reads (38%) | called by mutect2, pindel, varscan2
- GLRB | c.298-48A>C | Intron (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- HDAC1 | c.-14G>T | 5'UTR (SNP) | VAF 135/304 reads (44%) | catalogued as rs1200953255; called by muse, mutect2, varscan2
- HERC2 | c.13273-341G>T | Intron (SNP) | VAF 89/534 reads (17%) | called by muse, mutect2, varscan2
- IPO7 | c.85-9del | Intron (DEL) | VAF 82/217 reads (38%) | called by mutect2, varscan2
- KDM4C | c.2994+115del | Intron (DEL) | VAF 74/176 reads (42%) | catalogued as COSV101185245; called by mutect2, varscan2
- LARP1B | c.988+560C>A | Intron (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-5168G>T | Intron (SNP) | VAF 34/257 reads (13%) | called by muse, mutect2, varscan2
- LMBR1 | c.424-15910G>T | Intron (SNP) | VAF 11/141 reads (8%) | catalogued as rs1434172815; called by muse, mutect2
- MACROD2 | c.418+165029del | Intron (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- MAP9 | c.708+52dup | Intron (INS) | VAF 32/115 reads (28%) | catalogued as rs767747637; called by mutect2, pindel, varscan2
- MBD1 | c.*158C>T | 3'UTR (SNP) | VAF 182/440 reads (41%) | called by muse, mutect2, varscan2
- MIR296 | n.24dup | RNA (INS) | VAF 45/109 reads (41%) | catalogued as rs747039644; called by mutect2, varscan2
- MIR4739 | chr17:79707612 A>T | 5'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- MIR4771-1 | chr2:87193555 C>T | 5'Flank (SNP) | VAF 193/403 reads (48%) | called by muse, mutect2, varscan2
- MIR548A2 | n.53del | RNA (DEL) | VAF 85/257 reads (33%) | called by mutect2, pindel, varscan2
- MMGT1 | c.-41G>A | 5'UTR (SNP) | VAF 190/475 reads (40%) | called by muse, mutect2, varscan2
- NAA16 | c.1257+13T>A | Intron (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- NAA38 | c.81+62G>A | Intron (SNP) | VAF 9/152 reads (6%) | catalogued as rs1213545960, COSV99640697; called by muse, mutect2
- NPHP1 | c.1926+352del | Intron (DEL) | VAF 72/176 reads (41%) | catalogued as rs112428035; called by mutect2, varscan2
- ORAI3 | c.-14del | 5'UTR (DEL) | VAF 4/37 reads (11%) | called by pindel, varscan2
- PARVG | c.-12-15G>A | Intron (SNP) | VAF 110/263 reads (42%) | called by muse, mutect2, varscan2
- PHOX2B | c.*26G>A | 3'UTR (SNP) | VAF 38/184 reads (21%) | catalogued as rs1394696230; called by mutect2, varscan2
- PKD1P6 | n.4204C>T | RNA (SNP) | VAF 185/1066 reads (17%) | catalogued as rs559841071; called by muse, mutect2, varscan2
- PPP2R5C | c.1443+3243C>A | Intron (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- PSAP | c.*47del | 3'UTR (DEL) | VAF 48/383 reads (13%) | called by mutect2, pindel, varscan2
- PUS1 | c.441+44G>A | Intron (SNP) | VAF 20/415 reads (5%) | catalogued as rs1333413424; called by muse, mutect2
- RAB18 | c.*735del | 3'UTR (DEL) | VAF 102/662 reads (15%) | called by mutect2, pindel, varscan2
- RBPMS | c.528+4904G>T | Intron (SNP) | VAF 16/351 reads (5%) | called by muse, mutect2
- RN7SL211P | chr2:64904587 A>T | 3'Flank (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- RPP14 | c.-2del | 5'UTR (DEL) | VAF 101/275 reads (37%) | called by mutect2, pindel, varscan2
- RPS2 | c.709+67T>C | Intron (SNP) | VAF 89/341 reads (26%) | called by muse, mutect2, varscan2
- SCAI | c.1399+788C>T | Intron (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- SFTA3 | n.931G>T | RNA (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- SH3TC2 | c.280-1326del | Intron (DEL) | VAF 14/48 reads (29%) | catalogued as rs752479043; called by mutect2, varscan2
- SHISA5 | c.76+12del | Intron (DEL) | VAF 15/93 reads (16%) | catalogued as rs1361264563; called by mutect2, pindel, varscan2
- SLC17A9 | c.629-46G>A | Intron (SNP) | VAF 100/219 reads (46%) | catalogued as rs367609988; called by muse, mutect2, varscan2
- SMARCC1 | c.3043+5987G>A | Intron (SNP) | VAF 83/232 reads (36%) | catalogued as rs189596613; called by muse, mutect2, varscan2
- SOX10 | c.*26del | 3'UTR (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- SQSTM1 | c.*21T>C | 3'UTR (SNP) | VAF 79/456 reads (17%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.319-168dup | Intron (INS) | VAF 57/352 reads (16%) | called by mutect2, pindel, varscan2
- STIM2 | c.-20G>T | 5'UTR (SNP) | VAF 107/197 reads (54%) | catalogued as rs1396035123; called by muse, mutect2, varscan2
- SUMO2P21 | n.9C>T | RNA (SNP) | VAF 97/216 reads (45%) | called by muse, mutect2, varscan2
- TBCD | c.*19T>C | 3'UTR (SNP) | VAF 55/380 reads (14%) | called by muse, mutect2, varscan2
- TCIRG1 | c.631-35G>A | Intron (SNP) | VAF 197/451 reads (44%) | called by muse, mutect2, varscan2
- TMEM18 | c.58-574G>A | Intron (SNP) | VAF 87/351 reads (25%) | catalogued as rs1386957787; called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+45del | Intron (DEL) | VAF 45/124 reads (36%) | called by mutect2, pindel, varscan2
- TRIM56 | c.*2156del | 3'UTR (DEL) | VAF 22/190 reads (12%) | catalogued as rs748731606; called by mutect2, varscan2
- TRIML2 | c.621+783G>T | Intron (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- TTC37 | c.2779-38_2779-35del | Intron (DEL) | VAF 66/213 reads (31%) | called by mutect2, pindel, varscan2
- UGT1A7 | c.855+7746del | Intron (DEL) | VAF 41/270 reads (15%) | called by mutect2, pindel, varscan2
- UGT2B27P | n.681G>T | RNA (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2
- XIAP | c.-251del | 5'UTR (DEL) | VAF 44/304 reads (14%) | called by mutect2, pindel, varscan2
- Z83844.2 | c.-90-310C>T | Intron (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- ZFAT | c.2888-28G>T | Intron (SNP) | VAF 116/236 reads (49%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280691 A>G | 5'Flank (SNP) | VAF 31/175 reads (18%) | catalogued as rs201834741; called by muse, varscan2
